Surgical pathology report (de-identified scan), TCGA case TCGA-AZ-4681, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-AZ-4681-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: RIGHT OVARY AND FALLOPIAN TUBE, RIGHT SALPINGO-OOPHORECTOMY –

- A. ATROPHIC OVARY WITH OVARIAN FIBROMA, 1.2 CM.
- B. FALLOPIAN TUBE WITH MULTIPLE PARATUBAL CYSTS.
- C. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 2: LEFT OVARY AND FALLOPIAN TUBE, LEFT SALPINGO-OOPHORECTOMY –

- A. ATROPHIC OVARY WITH OVARIAN FIBROMATA, 2.8 CM AND 2.0 CM.
- B. FALLOPIAN TUBE WITH PARATUBAL CYSTS.
- C. THERE IS NO EVIDENCE OF MALIGNANCY.

PART 3: RECTUM, PROCTECTOMY –

- A. RECTAL ADENOCARCINOMA, MODERATELY DIFFERENTIATED, 2.5 CM IN GREATEST EXTENT.
- B. TUMOR EXTENDS THROUGH THE FULL THICKNESS OF THE MUSCULARIS PROPRIA INTO PERIRECTAL ADIPOSE TISSUE.
- C. THE MARGINS OF RESECTION ARE FREE OF MALIGNANCY.
- D. EIGHT LYMPH NODES, NO TUMOR SEEN (0/8).
- E. HISTOPATHOLOGIC STAGE: pTNM = T3 N0 MX.
- F. INCIDENTAL HYPERPLASTIC POLYPS.
- G. DIVERTICULAR DISEASE.

PART 4: RECTUM, MARGINS, RESECTION –
RECTUM, NO TUMOR SEEN.

PART 5: COLON, RIGHT, RIGHT HEMICOLECTOMY –

- A. COLONIC ADENOCARCINOMA, MODERATELY DIFFERENTIATED, 2.5 CM IN GREATEST EXTENT.
- B. TUMOR EXTENDS THROUGH THE FULL THICKNESS OF THE MUSCULARIS PROPRIA, INTO PERICOLONIC ADIPOSE TISSUE.
- C. THE MARGINS OF RESECTION ARE FREE OF MALIGNANCY.
- D. FIVE LYMPH NODES, NO TUMOR SEEN (0/5).
- E. HISTOPATHOLOGIC STAGE: pTNM = T3 N0 MX.
- F. APPENDIX WITH FIBROUS OBLITERATION OF THE TIP.
- G. DIVERTICULAR DISEASE.

PART 6: GALLBLADDER, CHOLECYSTECTOMY –
CHRONIC CHOLECYSTITIS AND CHOLELITHIASIS.

TCGA-AZ-4681

Source: NCI Genomic Data Commons file 5b5d6c6e-3057-4ff7-bb39-4a38d00e568e (TCGA-AZ-4681.F93F6D03-DDBC-4399-B896-88AD92B285E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).